Somatic mutation profile of tumor specimen TCGA-FD-A43Y-01A (aliquot TCGA-FD-A43Y-01A-21D-A26M-08) from TCGA case TCGA-FD-A43Y, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 65.4 years (23,889 days).
Specimen TCGA-FD-A43Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6a0c2ec-4a0c-493f-b9f2-c1fec5b59db5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A43Y-10A (Blood Derived Normal), aliquot TCGA-FD-A43Y-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abfd51bf-9af2-4560-a4e5-42d2443c6c24

The open-access MAF lists 69 somatic variants for this specimen: 51 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 15, Nonsense Mutation 5, Splice Site 3, Intron 2, In Frame Del 2, Frame Shift Del 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGAP4 | c.1364A>G p.H455R | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV101432590; called by muse, mutect2, varscan2
- AREL1 | c.1361A>G p.H454R | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs754333648, COSV62668126; called by muse, mutect2, varscan2
- ARPP19 | c.125_126insT p.K42Nfs*20 | Frame Shift Ins (INS) | VAF 18/88 reads (20%) | catalogued as COSV51119680; called by mutect2, pindel, varscan2
- ATG10 | c.551+1G>T p.X184_splice | Splice Site (SNP) | VAF 12/20 reads (60%) | catalogued as COSV56432972; called by muse, mutect2, varscan2
- ATM | c.1208C>G p.S403* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99586721; called by muse, mutect2, varscan2
- C8orf34 | c.1405G>T p.G469* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV57411103; called by muse, mutect2, varscan2
- C9orf78 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV59619394; called by muse, mutect2, varscan2
- CA3 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53411436; called by muse, mutect2, varscan2
- CD1E | c.301T>G p.F101V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV63771967; called by muse, mutect2
- CLEC4E | c.474G>T p.L158F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55227452; called by muse, mutect2, varscan2
- COA1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.243); catalogued as COSV56243985; called by muse, mutect2, varscan2
- COG2 | c.2189A>G p.K730R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs771271930, COSV100794565; called by muse, mutect2, varscan2
- CXXC1 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53276975; called by muse, mutect2, varscan2
- EEPD1 | c.806A>C p.Q269P | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV54203388; called by muse, mutect2, varscan2
- EPHA2 | c.154-2A>T p.X52_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100625984; called by muse, mutect2
- GPR6 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as COSV51573715; called by muse, mutect2, varscan2
- GRIK3 | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 81/623 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.848); catalogued as COSV66147226; called by muse, mutect2, varscan2
- HMCN1 | c.6664G>T p.G2222C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54943057; called by muse, mutect2, varscan2
- HPCAL4 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV65716712; called by muse, mutect2
- KIRREL1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV63288307; called by muse, mutect2, varscan2
- LEMD3 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1417326478, COSV100384130; called by muse, mutect2, varscan2
- LETMD1 | c.667C>G p.R223G | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV50400343; called by muse, mutect2, varscan2
- MARVELD2 | c.1142A>G p.Q381R | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs538762858, COSV57782476; called by muse, mutect2, varscan2
- MCMDC2 | c.68T>G p.F23C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58041265; called by muse, mutect2, varscan2
- MTMR4 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.657); catalogued as rs775203610, COSV60203997; called by muse, mutect2, varscan2
- MXRA5 | c.1568C>G p.A523G | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV54237715, COSV54251318; called by muse, mutect2, varscan2
- NFE2L2 | c.245A>T p.E82V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960018, COSV67961061, COSV67962846; called by muse, mutect2, varscan2
- NKAPL | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780227860, COSV59197581; called by muse, mutect2, varscan2
- OR5T1 | c.444G>A p.M148I | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV57305019; called by muse, mutect2, varscan2
- PCNX2 | c.2849G>A p.R950K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs369115693; called by muse, mutect2, varscan2
- PDE6B | c.547G>C p.G183R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55331054; called by muse, mutect2, varscan2
- PLEKHA4 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs771437881, COSV54366436, COSV99613414; called by muse, mutect2, varscan2
- PLEKHG4 | c.2266G>T p.E756* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV100430588; called by muse, mutect2
- PRPF8 | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV59261275, COSV59267985; called by muse, mutect2, varscan2
- RPTN | c.2110T>G p.W704G | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as COSV60166202, COSV60169286; called by muse, mutect2, varscan2
- SETD5 | c.3582G>T p.K1194N | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV56709466, COSV56717510; called by muse, mutect2, varscan2
- SPATA31D1 | c.4204G>A p.A1402T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as COSV100782389, COSV61201866; called by muse, mutect2, varscan2
- TNRC6C | c.4041C>G p.Y1347* | Nonsense Mutation (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100049304; called by muse, mutect2, varscan2
- TPMT | c.495-2A>G p.X165_splice | Splice Site (SNP) | VAF 4/29 reads (14%) | catalogued as COSV59430058; called by muse, mutect2, varscan2
- TTC21B | c.2428A>G p.K810E | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV54635459; called by muse, mutect2, varscan2
- USP51 | c.1736C>G p.S579C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101540637; called by muse, mutect2
- ZFC3H1 | c.328T>C p.F110L | Missense Mutation (SNP) | VAF 28/162 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.118); catalogued as COSV57350112; called by muse, mutect2, varscan2
- ZNF34 | c.1294A>T p.T432S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58641350; called by muse, mutect2
- ZNF423 | c.2098T>A p.Y700N (on ENST00000563137 / NM_001379286.1; = p.Y692N on NM_015069.4) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52205249; called by muse, mutect2, varscan2
- ZNF804B | c.3185T>G p.F1062C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV60856347; called by muse, mutect2, varscan2
- IGKV3-20 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- PGM5 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- S100A2 | c.236del p.F79Sfs*46 | Frame Shift Del (DEL) | VAF 60/224 reads (27%) | called by mutect2, pindel, varscan2
- SLC18A3 | c.486_488del p.M162_F163delinsI | In Frame Del (DEL) | VAF 14/104 reads (13%) | called by mutect2, pindel, varscan2
- TPTE | c.1575A>T p.R525S (on ENST00000618007 / NM_199261.4; = p.R507S on NM_199259.4) | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UGT2B28 | c.27_29del p.L11del | In Frame Del (DEL) | VAF 88/208 reads (42%) | called by pindel, varscan2
- ARHGAP26 | c.18C>G p.L6= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs752055794, COSV99188684; called by muse, varscan2
- ATP1A3 | c.2361C>T p.I787= (on ENST00000545399 / NM_001256214.2; = p.I774= on NM_152296.5) | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV57491377; called by muse, mutect2, varscan2
- BACH2 | c.1779C>T p.S593= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs373751160; called by muse, mutect2, varscan2
- CSMD1 | c.5292C>T p.V1764= (on ENST00000520002; = p.V1763= on NM_033225.6) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100141892; called by muse, mutect2
- FLT4 | c.3696C>T p.N1232= | Silent (SNP) | VAF 51/141 reads (36%) | catalogued as rs1188984263, COSV56123033; called by muse, mutect2, varscan2
- KLK13 | c.657G>A p.G219= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs754872494, COSV50067624; called by muse, mutect2, varscan2
- MSI2 | c.807G>C p.R269= | Silent (SNP) | VAF 32/159 reads (20%) | catalogued as COSV52368715; called by muse, mutect2, varscan2
- NBPF11 | c.621T>C p.C207= | Silent (SNP) | VAF 52/186 reads (28%) | called by muse, mutect2, varscan2
- PNPLA8 | c.1308A>C p.P436= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as COSV57554873; called by muse, mutect2, varscan2
- PTPRT | c.3555G>A p.V1185= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV62022892; called by muse, mutect2, varscan2
- PTPRZ1 | c.222T>C p.N74= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV101099246; called by muse, mutect2
- SMG7 | c.3144T>C p.T1048= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as rs1368297084, COSV61634387; called by muse, mutect2, varscan2
- TG | c.3738A>G p.Q1246= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs147657212; called by muse, mutect2, varscan2
- UNC5C | c.150A>G p.P50= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs779341478, COSV71662435; called by muse, mutect2, varscan2
- ZNF76 | c.1428C>T p.A476= | Silent (SNP) | VAF 11/91 reads (12%) | catalogued as COSV57355463; called by muse, mutect2, varscan2
- AGAP7P | n.1434A>G | RNA (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2, varscan2
- NOP56 | c.209-172C>T | Intron (SNP) | VAF 12/72 reads (17%) | catalogued as COSV100249900; called by muse, mutect2, varscan2
- TNK2 | c.-18-6790C>T | Intron (SNP) | VAF 5/17 reads (29%) | catalogued as COSV57376191; called by muse, mutect2, varscan2
